Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A4BV, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A4BV-01A (Primary Tumor).

[page 1 of 3]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY

Status: Edited MyChart: Not Released

Surgical Pathology

Department of Pathology

Surgical Pathology Laboratory

Surgical Pathology Report

Patient:

Age/Sex: / M

CLINICAL INFORMATION:

Prostate cancer.

Specimens submitted: A. Apical margin; B. Prostate gland and seminal vesicles; C. Pelvic lymph node; D. Anterior prostatic fat

INTRAOPERATIVE DIAGNOSIS:

A. Frozen section diagnosis: Fibromuscular tissue and nerve.

No tumor. No glands

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "apical margin" and consists of a 0.2 x 0.2 x 0.1 cm piece of red-tan soft tissue. The specimen is entirely submitted for frozen section diagnosis. Summary of sections: AFSC.

B. Received fresh, the specimen is labeled "prostate glands and seminal vesicles", and consists of a 62.4 gram radical prostatectomy specimen including a 6.5 x 4.5 x 4.0 cm prostate, a 3.0 x 1.0 x 0.5 cm left seminal vesicle, a 2.0 x 0.5 x 0.5 cm left vas deferens, a 2.0 x 1.5 x 0.5 cm right seminal vesicle and a 3.0 x 0.5 x 0.5 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to D respectively. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted alternative sections.

ICD-O-3
CQCF: Adenocarcinoma, acinar 8550/3
Path: Adenocarcinoma, NOS 8140/3
Site: Prostate, NOS C61.9
lu 9/24/12

[page 2 of 3]
Summary of sections: B1-right seminal vesicle and vas deferens; B2-left seminal vesicle and vas deferens; B3-RA base; B4-RP Base; B5-LA base; B6-LP base; B7-RA apex; B8-RP apex; B9-LA apex; B10-LP apex; B11-ARA; B12-ARM; B13-ARP; B14-ALA; B15-ALM; B16-ALP; B17-CRA; B18 to B19-CRM; B20-CRP; B21-CLA; B22 to B23-CLM; B24-CLP; B25-DRA; B26 to B27-DRM; B28-DRP; B29-DLA; B30 to B31-DLM; B32-DLP. Note: (R=Right; L=Left; A=Anterior; P=Posterior; M=Mid).

C. Received fresh, the specimen is labeled "pelvic lymph node" and consists of a 5.0 x 3.0 x 1.0 cm aggregate of lymph nodes with attached fat. The specimen is entirely submitted. Summary of sections: C1 to C3.

D. Received fresh, the specimen is labeled "anterior prostatic fat" and consists of a 4.0 x 3.0 x 2.0 cm aggregate of fatty tissue. The specimen is entirely submitted. Summary of sections: D1 to D3.

DIAGNOSIS:

A. Apical margin (biopsy):

Benign fibromuscular tissue and nerve.
No prostatic glands or carcinoma seen.

B. Prostate, seminal vesicles and vas deferens (radical prostatectomy):

Prostatic adenocarcinoma, Gleason score 9(4+5),
tertiary 3 (as per unilateral, with
multifocal extra-prostatic extension.
There is preferential perineural invasion.
Seminal vesicles and inked surgical margins are
negative for carcinoma.
Please see synoptic summary.

C. Pelvic lymph nodes (excision):

Ten lymph nodes negative for metastatic carcinoma
(0/10).

D. Anterior fat (biopsy):

Benign fibroadipose tissue.
No carcinoma seen.

SYNOPTIC DIAGNOSIS:

Histologic Type:	Adenocarcinoma
(conventional, not otherwise specified)	
	Primary Pattern: Grade 4
	Secondary Pattern: Grade 5
	Tertiary Pattern: Grade 3
	Total Gleason Score: 9
Tumor Quantitation:	Proportion (percent) of
prostatic tissue involved by tumor: 15%	
Pathologic Staging (pTNM):	pT3a: Extraprostatic
extension	
	pN0: No regional lymph
node metastasis	
	Number of regional lymph
nodes examined: 10	
	Number of regional lymph

[page 3 of 3]
nodes involved: 0

cannot be assessed

Margins:

invasive carcinoma

Extraprostatic Extension:

Seminal Vesicle Invasion:

Perineural Invasion:

Venous (Large Vessel) Invasion (V): Absent

Lymphatic (Small Vessel) Invasion (L): Absent

Additional Pathologic Findings: Inflammation: Chronic

hyperplasia

pMX: Distant metastasis

Margins uninvolved by

Multifocal present

Absent

Present

Benign prostatic

** Electronically Signed Out **

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

ICD9 Codes: A-D: 185

SNOMED:

Slides: A-3, B-32, C-3, D-3

Amendments

Reason: Clerical Error

Missing information on Specimen C

Resulting Agency

VC=Value has a corrected status

8/24/12

Source: NCI Genomic Data Commons file 60197ae3-d84a-45b2-ad0d-a184da291e73 (TCGA-KC-A4BV.CC0244A3-48CF-4448-A7F1-5DB9EC3B823A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).